Gene-level copy-number profile of tumor specimen TCGA-61-1910-01A from TCGA case TCGA-61-1910, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 56.9 years (20,779 days).
Specimen TCGA-61-1910-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5cfffde5-d299-47e2-8016-f4959d6c88f2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1910-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3575c049-97d0-43b0-8d0a-514c71941916

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 15,442; copy number 2: 33,340; copy number 3: 7,944; copy number 4: 1,938; copy number 5: 843; copy number 6: 116; copy number 7: 190.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1910-01A-01D-0577-01): tumor purity 0.97, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,149 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,666,559–169,998,373, 30 genes, copy number 5 (within-gene range 4–5): RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1.
- chr3:172,425,850–180,982,753, 119 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:39,733,430–39,949,755, 10 genes, copy number 5 (within-gene range 3–5): LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1.
- chr7:145,583,197–148,420,998, 15 genes, copy number 5 (within-gene range 4–5): DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2, RNU6-1184P, RNA5SP249, RN7SL456P.
- chr8:118,620,498–145,066,685, 483 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr11:72,080,331–73,662,819, 62 genes, copy number 5 (broad region; genes not listed).
- chr15:71,792,638–82,836,108, 358 genes, copy number 5 (broad region; genes not listed).
- chr15:100,547,765–100,651,701, 7 genes, copy number 6 (within-gene range 4–6): AC027020.2, RNU6-322P, PRKXP1, AC027020.1, LINS1, RNU6-181P, ASB7.
- chr20:87,250–2,075,822, 64 genes, copy number 5 (broad region; genes not listed).
- chr20:2,107,900–2,109,991, 1 gene, copy number 5: AL359916.1.

Autosomal genes at a single copy (total copy number 1): 13,027. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
